Somatic mutation profile of tumor specimen TCGA-JY-A93F-01A (aliquot TCGA-JY-A93F-01A-21D-A37C-09) from TCGA case TCGA-JY-A93F, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IB; Tumor grade: G1; Age at diagnosis: 58.2 years (21,257 days).
Specimen TCGA-JY-A93F-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 947ff337-4fca-460f-a2ba-0ab6265c7d3c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-JY-A93F-10A (Blood Derived Normal), aliquot TCGA-JY-A93F-10A-01D-A37F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3f91a4d5-284f-48f5-86ca-0129ec5e6e1a

The open-access MAF lists 101 somatic variants for this specimen: 76 protein-altering or splice-affecting, 21 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 60, Silent 21, Nonsense Mutation 5, Frame Shift Del 4, Splice Site 3, Frame Shift Ins 2, 5'Flank 1, Translation Start Site 1, Intron 1, In Frame Del 1, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT2A | c.3461G>A p.R1154Q | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1131691799, COSV63286260, COSV63290453; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- KMT2D | c.12985C>T p.Q4329* | Nonsense Mutation (SNP) | VAF 14/58 reads (24%) | catalogued as rs1555187758, COSV56445048; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SMARCA4 | c.2729C>T p.T910M | Missense Mutation (SNP) | VAF 9/35 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1238758086, COSV60785486, COSV60802491; ClinVar: other / uncertain significance; called by muse, mutect2, varscan2
- ADGRB1 | c.3961G>A p.G1321S | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.174); catalogued as rs774828542, COSV60091234; called by muse, mutect2, varscan2
- AL592490.1 | c.496G>A p.V166I | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs1201475649, COSV69426103; called by muse, mutect2, varscan2
- ARHGEF17 | c.2119C>T p.R707C | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs369681028; called by muse, mutect2, varscan2
- BCAP31 | c.673C>T p.R225C | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1557047451, COSV100798865; called by muse, mutect2, varscan2
- CYTH1 | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as rs1377795513, COSV63119986; called by muse, mutect2, varscan2
- DFFB | c.419C>T p.P140L | Missense Mutation (SNP) | VAF 45/126 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.147); catalogued as rs773522402; called by muse, mutect2, varscan2
- DNAH5 | c.13846G>A p.G4616R | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54246149; called by muse, mutect2, varscan2
- ELP6 | c.280G>A p.V94I | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as rs759438726, COSV56132217; called by muse, mutect2, varscan2
- FAXC | c.1055G>A p.S352N | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.011); catalogued as rs1319851499; called by muse, mutect2
- GALNTL5 | c.1219T>C p.Y407H | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs779333636; called by muse, mutect2, varscan2
- GEMIN7 | c.38G>A p.R13Q | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs1206374120; called by muse, mutect2, varscan2
- HDLBP | c.3437G>A p.R1146H | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.891); catalogued as rs768699303, COSV60492615; called by muse, mutect2, varscan2
- IFNGR1 | c.805del p.Y269Ifs*8 | Frame Shift Del (DEL) | VAF 22/54 reads (41%) | catalogued as CD1312348; called by mutect2, pindel, varscan2
- KIAA1191 | c.514G>T p.A172S | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as COSV100055511; called by muse, mutect2, varscan2
- KIAA1549 | c.848T>A p.L283* | Nonsense Mutation (SNP) | VAF 11/28 reads (39%) | catalogued as COSV54318481; called by muse, mutect2, varscan2
- KMT2A | c.1147dup p.A383Gfs*6 | Frame Shift Ins (INS) | VAF 8/22 reads (36%) | catalogued as COSV100629540; called by mutect2, pindel, varscan2
- KRT5 | c.1168A>G p.N390D | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV52858590; called by muse, varscan2
- LRRC4C | c.526C>T p.R176* | Nonsense Mutation (SNP) | VAF 12/37 reads (32%) | catalogued as rs1394680745, COSV53419648, COSV99538016; called by muse, mutect2, varscan2
- NBN | c.2232del p.F744Lfs*7 | Frame Shift Del (DEL) | VAF 9/56 reads (16%) | catalogued as rs1554554233, COSV99620083; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- NEXMIF | c.4197C>A p.S1399R | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.165); catalogued as rs774480770; called by muse, mutect2, varscan2
- NHLRC3 | c.1009C>T p.P337S | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs900057279; called by muse, mutect2, varscan2
- NOLC1 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 14/57 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.892); catalogued as rs762663571; called by muse, mutect2, varscan2
- NOTCH3 | c.5005C>T p.R1669C | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1245716605; called by muse, mutect2, varscan2
- NRG1 | c.1516G>A p.A506T (on ENST00000405005 / NM_013964.5; = p.A511T on NM_013956.5) | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.026); catalogued as rs376858256; called by muse, mutect2, varscan2
- NUB1 | c.1118G>A p.R373Q | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.014); catalogued as rs373576077; called by muse, mutect2, varscan2
- PPFIA2 | c.536C>A p.S179Y | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV61020185; called by muse, mutect2, varscan2
- PTEN | c.644T>G p.F215C | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV64289103; called by muse, mutect2, varscan2
- RTTN | c.460C>A p.Q154K | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.254); catalogued as COSV55347859; called by muse, mutect2, varscan2
- SH3GL3 | c.241G>A p.V81M | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.627); catalogued as rs764980950; called by muse, mutect2, varscan2
- SMAD3 | c.1247C>T p.S416F | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV59286689; called by muse, mutect2, varscan2
- SPEF2 | c.5428G>A p.G1810R | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.311); catalogued as rs1434600092; called by muse, mutect2, varscan2
- SPSB3 | c.607C>T p.H203Y | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs756651857; called by muse, mutect2, varscan2
- TGFBR2 | c.1589C>T p.T530I | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM093626, COSV55452895; called by muse, mutect2, varscan2
- TRIM16L | c.782C>T p.T261M | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as rs1447154923, COSV67459089, COSV67459687; called by muse, mutect2, varscan2
- ZNF184 | c.1490C>T p.T497M | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs759048815; called by muse, mutect2, varscan2
- ZNF581 | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs201594382, COSV54402358; called by muse, mutect2, varscan2
- ZNF608 | c.272C>T p.S91F | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as COSV100102324, COSV60441885; called by muse, mutect2, varscan2
- ACCS | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ADNP2 | c.2206G>C p.A736P | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- APC2 | c.1105C>G p.R369G | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ARID1A | c.3216dup p.W1073Mfs*32 | Frame Shift Ins (INS) | VAF 17/61 reads (28%) | called by mutect2, pindel, varscan2
- ARSB | c.1169A>T p.E390V | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- BASP1 | c.123G>T p.E41D | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- DRC1 | c.1510-2A>T p.X504_splice | Splice Site (SNP) | VAF 20/48 reads (42%) | called by muse, varscan2
- ECI1 | c.571G>C p.D191H | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- ELOVL6 | c.557C>A p.A186E | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- ERBIN | c.1351G>A p.E451K | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- FREM2 | c.5788C>T p.P1930S | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.543); called by muse, mutect2
- FSD1 | c.1130G>T p.S377I | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- GPR26 | c.368C>T p.A123V | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- ITGA9 | c.2717G>T p.S906I | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.285); called by muse, mutect2
- KCNB2 | c.546G>T p.L182F | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- KDM3B | c.4152G>C p.W1384C | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KIAA1109 | c.2794-1G>A p.X932_splice | Splice Site (SNP) | VAF 23/49 reads (47%) | called by muse, mutect2, varscan2
- MAGEC1 | c.550G>T p.E184* | Nonsense Mutation (SNP) | VAF 58/260 reads (22%) | called by muse, varscan2
- MUC17 | c.1309G>T p.A437S | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- NLRC5 | c.1723_1726del p.P575Sfs*20 | Frame Shift Del (DEL) | VAF 8/15 reads (53%) | called by mutect2, varscan2
- NSD1 | c.5893-1G>A p.X1965_splice | Splice Site (SNP) | VAF 22/67 reads (33%) | called by muse, mutect2, varscan2
- PDZD2 | c.8011C>T p.L2671F | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PPP1R18 | c.385A>G p.M129V | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- RNF43 | c.2340_2352del p.Q781Mfs*42 | Frame Shift Del (DEL) | VAF 16/46 reads (35%) | called by mutect2, varscan2
- ROS1 | c.5117G>T p.C1706F | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- RYR1 | c.11667G>T p.L3889F | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLCO1B1 | c.1555G>T p.A519S | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- SNAI2 | c.740C>T p.S247F | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- SNCAIP | c.1946C>T p.S649F | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- SPACA9 | c.490C>T p.Q164* | Nonsense Mutation (SNP) | VAF 21/78 reads (27%) | called by muse, mutect2, varscan2
- STXBP5L | c.2734C>T p.P912S | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.84); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TDRKH | c.1027C>A p.H343N | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- TOP1 | c.506_507+1del | In Frame Del (DEL) | VAF 7/30 reads (23%) | called by mutect2, pindel, varscan2
- XRRA1 | c.1408C>T p.P470S | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- ZC3H12A | c.661G>T p.V221L | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- ZNF134 | c.776C>T p.P259L | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BLNK | c.978C>A p.P326= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV56412762; called by muse, mutect2, varscan2
- CHST7 | c.841A>C p.R281= | Silent (SNP) | VAF 6/27 reads (22%) | called by muse, mutect2, varscan2
- CIITA | c.2023C>T p.L675= | Silent (SNP) | VAF 11/19 reads (58%) | called by muse, mutect2, varscan2
- DGKQ | c.2091G>A p.P697= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as rs770688103; called by muse, mutect2, varscan2
- DHX8 | c.1128C>T p.V376= | Silent (SNP) | VAF 23/68 reads (34%) | called by muse, mutect2, varscan2
- DTNBP1 | c.618C>T p.D206= | Silent (SNP) | VAF 22/67 reads (33%) | called by muse, mutect2, varscan2
- IL7 | c.141A>G p.Q47= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as rs764670407; called by muse, mutect2, varscan2
- IRS4 | c.3408G>A p.A1136= | Silent (SNP) | VAF 12/45 reads (27%) | called by muse, mutect2, varscan2
- KRT5 | c.132T>G p.G44= | Silent (SNP) | VAF 32/124 reads (26%) | called by muse, mutect2, varscan2
- KRT85 | c.807C>T p.A269= | Silent (SNP) | VAF 25/67 reads (37%) | catalogued as rs1187205108; called by muse, mutect2, varscan2
- LRP4 | c.4245C>T p.N1415= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as rs185084650; called by muse, varscan2
- MECP2 | c.1446C>T p.T482= | Silent (SNP) | VAF 25/74 reads (34%) | catalogued as rs76895094; ClinVar: benign; called by muse, mutect2, varscan2
- OR6A2 | c.663C>A p.A221= | Silent (SNP) | VAF 7/22 reads (32%) | called by muse, mutect2, varscan2
- PDZD7 | c.78C>T p.S26= | Silent (SNP) | VAF 38/106 reads (36%) | catalogued as rs1309226749; called by muse, mutect2, varscan2
- PGGHG | c.1533C>T p.F511= | Silent (SNP) | VAF 11/31 reads (35%) | called by muse, mutect2, varscan2
- PKP4 | c.1317G>A p.Q439= | Silent (SNP) | VAF 21/65 reads (32%) | called by muse, mutect2, varscan2
- SLC25A32 | c.78G>A p.L26= | Silent (SNP) | VAF 19/84 reads (23%) | catalogued as rs1194763006; called by muse, mutect2, varscan2
- TMEM252 | c.267C>T p.A89= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as rs1324169820, COSV66065846; called by muse, mutect2, varscan2
- VAX2 | c.573G>T p.L191= | Silent (SNP) | VAF 25/71 reads (35%) | called by muse, mutect2, varscan2
- XRCC1 | c.348G>A p.L116= | Silent (SNP) | VAF 22/61 reads (36%) | called by muse, mutect2, varscan2
- ZNF667 | c.1447C>A p.R483= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as COSV52640415; called by muse, mutect2, varscan2
- C17orf58 | c.103+23C>G | Intron (SNP) | VAF 14/45 reads (31%) | catalogued as rs1555699406; called by muse, mutect2, varscan2
- SH3BP1 | c.*289G>A | 3'UTR (SNP) | VAF 22/73 reads (30%) | catalogued as rs766207269; called by muse, mutect2, varscan2
- TUBB4AP1 | n.459G>C | RNA (SNP) | VAF 30/76 reads (39%) | called by muse, varscan2
- ZNF467 | chr7:149777712 C>A | 5'Flank (SNP) | VAF 28/72 reads (39%) | called by muse, mutect2, varscan2
